Somatic mutation profile of tumor specimen TCGA-GF-A6C8-06A (aliquot TCGA-GF-A6C8-06A-12D-A30X-08) from TCGA case TCGA-GF-A6C8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.3 years (22,767 days).
Specimen TCGA-GF-A6C8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09db08d3-b296-4176-9a6a-53f3c70603c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A6C8-10A (Blood Derived Normal), aliquot TCGA-GF-A6C8-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6abbbd1-bba8-44df-aaac-9b9d3045319c

The open-access MAF lists 450 somatic variants for this specimen: 297 protein-altering or splice-affecting, 144 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 270, Silent 144, Nonsense Mutation 15, Splice Site 7, RNA 4, Intron 3, Splice Region 2, Frame Shift Ins 1, 3'Flank 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56984819, COSV56985325; called by muse, mutect2, varscan2
- MTM1 | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as rs587783763, COSV60334819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- SCN2A | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1057520844, COSV51839526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5785C>T p.P1929S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs766342460, COSV70027839; called by muse, mutect2, varscan2
- ABI1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV61016642; called by muse, mutect2, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by muse, mutect2, varscan2
- ACOT11 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56363901; called by muse, mutect2, varscan2
- ADAM18 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55846867; called by muse, mutect2, varscan2
- ADAM22 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs866397413, COSV55975839; called by muse, mutect2, varscan2
- ADAMTS6 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58682854; called by muse, mutect2, varscan2
- ADGRV1 | c.11563G>A p.E3855K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774378608, COSV67980003; called by muse, mutect2, varscan2
- AGBL1 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765083113, COSV69798424; called by muse, mutect2, varscan2
- AGL | c.4418C>T p.T1473I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs902331738, COSV54052132; called by muse, mutect2, varscan2
- ALDOB | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66397766; called by muse, mutect2, varscan2
- ALPP | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV67396264; called by muse, mutect2, varscan2
- APOB | c.7924C>T p.P2642S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51921485; called by muse, mutect2, varscan2
- ARHGAP17 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV51506607; called by muse, mutect2, varscan2
- ARHGAP18 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV63764348; called by muse, mutect2, varscan2
- ARHGAP28 | c.1822C>T p.L608F (on ENST00000383472 / NM_001366230.1; = p.L449F on NM_001010000.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51636500, COSV51637319; called by muse, mutect2, varscan2
- ARHGEF40 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.456); catalogued as rs1167118016, COSV53880017; called by muse, mutect2, varscan2
- ARID1B | c.5917C>T p.P1973S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51660055; called by muse, mutect2, varscan2
- ARMC2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52900307; called by muse, mutect2, varscan2
- ARSF | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63839509; called by muse, mutect2, varscan2
- ASB12 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1298297861, COSV62856043; called by muse, mutect2, varscan2
- ASB4 | c.978+1G>A p.X326_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV57944793; called by muse, mutect2, varscan2
- ASMTL | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.778); catalogued as COSV67243542; called by muse, mutect2, varscan2
- ATAD3B | c.394C>T p.R132C (on ENST00000308647; = p.R238C on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs757344083, COSV100426461, COSV58020515; called by muse, mutect2, varscan2
- ATP8B4 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52714450; called by muse, mutect2, varscan2
- ATR | c.6916C>T p.L2306F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63386154, COSV63387052; called by muse, mutect2, varscan2
- ATRX | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs781932965, COSV64874076; called by muse, mutect2, varscan2
- B4GALNT2 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55925310, COSV55925895; called by muse, mutect2, varscan2
- BCLAF3 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1267227597, COSV61413774; called by muse, mutect2, varscan2
- BCOR | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100653412, COSV60705926, COSV60706170; called by muse, mutect2, varscan2
- BMT2 | c.770G>A p.W257* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV51776355; called by muse, mutect2, varscan2
- BRAT1 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV61395170; called by muse, mutect2, varscan2
- BRWD3 | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV64747483; called by muse, mutect2, varscan2
- BTBD3 | c.1150C>G p.R384G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV54779015; called by muse, mutect2, varscan2
- BTNL3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61564826; called by muse, mutect2, varscan2
- C11orf80 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.357); catalogued as COSV60929097; called by muse, mutect2, varscan2
- CARD11 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV62754649; called by muse, mutect2, varscan2
- CASP5 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52828382; called by muse, mutect2, varscan2
- CASS4 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64386275, COSV64388351; called by muse, mutect2, varscan2
- CATSPERG | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as COSV53046919; called by muse, mutect2, varscan2
- CCDC151 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV62697786; called by muse, mutect2, varscan2
- CCDC181 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as COSV63156315; called by muse, mutect2, varscan2
- CCDC25 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV62958691; called by muse, mutect2, varscan2
- CCR5 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs149975182; called by muse, mutect2, varscan2
- CD163 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766660196, COSV63131903; called by muse, mutect2, varscan2
- CDH20 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV53009029; called by muse, mutect2, varscan2
- CDH20 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.777); catalogued as COSV53009040; called by muse, mutect2, varscan2
- CDRT1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs202021798, COSV55411909; called by muse, mutect2, varscan2
- CEMIP | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV99586553; called by muse, mutect2, varscan2
- CFAP61 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs754130374, COSV55627777; called by muse, mutect2
- CFAP65 | c.4204G>A p.G1402R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58560557; called by muse, mutect2
- CGGBP1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV58851770; called by muse, mutect2, varscan2
- CHAF1B | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs756979003, COSV58439960; called by muse, mutect2, varscan2
- CKAP2 | c.212T>C p.V71A (on ENST00000378037 / NM_001098525.2; = p.V70A on NM_018204.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV51621848; called by muse, mutect2, varscan2
- CLDN18 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99480758; called by muse, varscan2
- CLDN18 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV51737658; called by muse, varscan2
- COL11A1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV62182145; called by muse, mutect2, varscan2
- CPAMD8 | c.2905G>A p.D969N (on ENST00000651564; = p.D922N on NM_015692.5) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV71596500; called by muse, mutect2, varscan2
- CRK | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56030440; called by muse, mutect2, varscan2
- CRYBB3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774418603, COSV53194472; called by muse, mutect2, varscan2
- CSMD2 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53885303; called by muse, mutect2, varscan2
- CSMD3 | c.3159C>A p.N1053K (on ENST00000297405 / NM_001363185.1; = p.N949K on NM_052900.3) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as rs1005865709, COSV52125496; called by muse, mutect2, varscan2
- CSPG4 | c.4657G>A p.D1553N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs1185686905, COSV57894462; called by muse, mutect2, varscan2
- CUL4B | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV60685068; called by muse, mutect2, varscan2
- CUTC | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs1275631251, COSV65081597; called by muse, mutect2, varscan2
- CYP7B1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV59582903; called by muse, mutect2, varscan2
- DAB1 | c.1265C>T p.T422I (on ENST00000371231; = p.T389I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1557545640, COSV64692713; called by muse, mutect2, varscan2
- DACH2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64167671; called by muse, mutect2, varscan2
- DCC | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs1406742141, COSV100498666, COSV59088400, COSV59131458; called by muse, mutect2, varscan2
- DCX | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as CM087669, COSV100576763, COSV57568905; called by muse, mutect2, varscan2
- DDX53 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV60068968; called by muse, mutect2, varscan2
- DENND1B | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs1356731439, COSV52463346; called by muse, mutect2, varscan2
- DMBX1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs760474949, COSV63601963; called by muse, mutect2, varscan2
- DMRT2 | c.1606T>C p.S536P | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); catalogued as COSV52401760; called by muse, mutect2, varscan2
- DNAH2 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50014332; called by muse, mutect2, varscan2
- DNAH7 | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751541338, COSV56756184; called by muse, mutect2, varscan2
- DOT1L | c.4475C>T p.S1492F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67109498; called by muse, mutect2, varscan2
- DSCAML1 | c.5207G>A p.G1736E (on ENST00000321322; = p.G1676E on NM_020693.4) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs1270937039, COSV58389589; called by muse, mutect2, varscan2
- EEF1G | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61321535; called by muse, mutect2
- EFNA5 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60949116; called by muse, mutect2, varscan2
- EGR3 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as COSV57833381; called by muse, mutect2
- EPHB2 | c.2531G>A p.R844Q (on ENST00000400191 / NM_001309193.2; = p.R845Q on NM_004442.7) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755816176, COSV65862266; called by muse, mutect2, varscan2
- EPHB3 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773303627, COSV57805649; called by muse, mutect2, varscan2
- EPHX1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55300417; called by muse, mutect2, varscan2
- ERICH3 | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.329); catalogued as rs1307015066, COSV58605655; called by muse, mutect2, varscan2
- EVPL | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.069); catalogued as COSV100044361; called by muse, mutect2, varscan2
- EZH1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV70549267; called by muse, mutect2, varscan2
- F5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV63123520; called by muse, mutect2, varscan2
- FAM124B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1280865122, COSV54739336; called by muse, mutect2, varscan2
- FAM135B | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV50525588, COSV99356539; called by mutect2, varscan2
- FAM47A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs868604600, COSV60496235; called by muse, varscan2
- FAM47C | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.458); catalogued as COSV63726254; called by muse, mutect2, varscan2
- FANCD2 | c.4211C>T p.S1404F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99811058; called by muse, mutect2, varscan2
- FER1L6 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV67549670; called by muse, mutect2, varscan2
- FLG | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 123/363 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.867); catalogued as COSV64241134, COSV64242268, COSV64251547; called by muse, mutect2, varscan2
- FLII | c.2468T>C p.L823P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV57497700; called by muse, mutect2, varscan2
- FLNC | c.3265G>A p.G1089R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554399171, COSV57954645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT3 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.147); catalogued as COSV99430127; called by muse, mutect2, varscan2
- FLT3 | c.526A>T p.M176L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54052050, COSV54069185; called by muse, mutect2, varscan2
- FOXA2 | c.1174C>T p.H392Y (on ENST00000377115 / NM_153675.3; = p.H398Y on NM_021784.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs1462699246, COSV65796189; called by muse, mutect2
- FOXRED2 | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV53399754; called by muse, mutect2, varscan2
- FSD1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55695912; called by muse, mutect2, varscan2
- GAB4 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs1232493988, COSV68753734; called by muse, mutect2, varscan2
- GALNT8 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV52897124; called by muse, mutect2, varscan2
- GDI1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50131078; called by muse, mutect2, varscan2
- GLB1L3 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs760273413, COSV68392669; called by muse, mutect2, varscan2
- GNAI1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204209552, COSV63522708; called by muse, mutect2, varscan2
- GPR137B | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63990891; called by muse, mutect2, varscan2
- GRIN3A | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62453155; called by muse, mutect2, varscan2
- GSPT1 | c.172C>T p.P58S (on ENST00000420576 / NM_001130007.2; = p.P196S on NM_002094.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV101341716; called by muse, mutect2, varscan2
- GUSB | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59221683; called by muse, mutect2, varscan2
- HAO2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs866039470, COSV58038810; called by muse, mutect2, varscan2
- HGD | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52197872; called by muse, mutect2, varscan2
- HIPK4 | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as COSV52520793; called by muse, mutect2, varscan2
- HNRNPM | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV57692524; called by muse, mutect2, varscan2
- HOXD3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs750214719, COSV50879923; called by muse, mutect2, varscan2
- HUS1B | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1264773686, COSV57863447; called by muse, mutect2, varscan2
- IFNA13 | c.28A>T p.M10L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV71924487; called by muse, mutect2, varscan2
- IGHV1-2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs200903159; called by muse, mutect2, varscan2
- INTS2 | c.3541C>T p.P1181S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.991); catalogued as COSV51998886; called by muse, mutect2, varscan2
- IQCN | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV66574148; called by muse, mutect2, varscan2
- IQUB | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV61238882; called by muse, mutect2, varscan2
- ITGA11 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs765501789, COSV59877253; called by muse, mutect2
- ITGAD | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1254569101, COSV66757806; called by muse, mutect2, varscan2
- ITGAL | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 121/394 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.047); catalogued as COSV63322013; called by muse, mutect2, varscan2
- ITIH2 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV64432975, COSV64435333; called by muse, mutect2, varscan2
- KCNB2 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs866710129, COSV73049516; called by muse, mutect2, varscan2
- KCNIP4 | c.164-1G>A p.X55_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV62849327; called by muse, mutect2, varscan2
- KCNQ1 | c.1792A>C p.K598Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.241); catalogued as COSV50107201; called by muse, mutect2, varscan2
- KIAA1210 | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV68176926; called by muse, mutect2, varscan2
- KIR3DL1 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs375462085; called by muse, mutect2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KYNU | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748827582, COSV51582784; called by muse, mutect2, varscan2
- L3MBTL3 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100695962; called by muse, mutect2, varscan2
- L3MBTL4 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV53121091; called by muse, mutect2, varscan2
- LAG3 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52567323; called by muse, mutect2, varscan2
- LAMB2 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as rs759042337, CM085510, COSV59733077; called by muse, mutect2, varscan2
- LAMB4 | c.2333G>A p.G778E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV52718219; called by muse, mutect2, varscan2
- LCE1B | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as rs202068251, COSV63980294; called by muse, mutect2, varscan2
- LPIN2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.572); catalogued as rs766189065, COSV55239479; called by muse, mutect2, varscan2
- MAGT1 | c.338G>A p.R113K (on ENST00000618282 / NM_001367916.1; = p.R145K on NM_032121.5) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63781494; called by muse, mutect2, varscan2
- MAP1A | c.6559C>T p.R2187C | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs200309835, COSV100288482; called by muse, mutect2, varscan2
- MAP3K15 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV58828662; called by muse, mutect2, varscan2
- MAP4K4 | c.2755C>T p.R919C (on ENST00000347699 / NM_001242559.2; = p.R837C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs375228116; called by muse, mutect2, varscan2
- MAPK4 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs757297774, COSV101245355, COSV68541953; called by muse, mutect2, varscan2
- MCM8 | c.2432T>C p.V811A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1439694714, COSV54513303; called by muse, mutect2
- MDH1B | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65589283; called by muse, mutect2, varscan2
- MEF2D | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV61728042; called by muse, mutect2, varscan2
- METTL22 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50837685; called by muse, mutect2, varscan2
- MMAA | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV55579960; called by muse, mutect2, varscan2
- MORF4L2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV64610966; called by muse, mutect2, varscan2
- MSN | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.364); catalogued as COSV64303918; called by muse, mutect2
- MST1R | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1471738292, COSV56568266; called by muse, mutect2, varscan2
- MUC16 | c.30596C>T p.S10199F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV67462730; called by muse, mutect2, varscan2
- MUC16 | c.10907C>T p.T3636I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV67462736; called by muse, mutect2, varscan2
- MUC16 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV67462742; called by muse, mutect2, varscan2
- MUC17 | c.11083C>T p.P3695S | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV60287338; called by muse, mutect2, varscan2
- MXRA5 | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54233684, COSV54246466; called by muse, mutect2, varscan2
- MYH1 | c.5470C>T p.R1824C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376061795; called by muse, mutect2, varscan2
- NCAN | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs761502466, COSV53050465; called by muse, mutect2, varscan2
- NCKAP5 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV58441214; called by muse, mutect2, varscan2
- NEXMIF | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV50029296; called by muse, mutect2, varscan2
- NFATC1 | c.1959+1G>A p.X653_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV53699608, COSV53704994; called by muse, mutect2, varscan2
- NLRP8 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769694462, COSV52586652, COSV99405303; called by muse, mutect2, varscan2
- NPAS3 | c.227A>G p.K76R (on ENST00000356141 / NM_001164749.2; = p.K46R on NM_022123.3) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV58083787; called by muse, mutect2, varscan2
- NPR2 | c.2047+1G>A p.X683_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | catalogued as COSV100438858; called by muse, mutect2, varscan2
- NPR2 | c.2047+2T>A p.X683_splice | Splice Site (SNP) | VAF 32/74 reads (43%) | catalogued as COSV100438859; called by muse, mutect2, varscan2
- NR1H3 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68008305, COSV68008346; called by muse, mutect2, varscan2
- NRROS | c.1835C>G p.T612R | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV60745686; called by muse, mutect2, varscan2
- NSD1 | c.6376G>C p.D2126H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61775583; called by muse, mutect2, varscan2
- NTHL1 | c.160C>T p.P54S (on ENST00000219066; = p.P46S on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99526254; called by muse, mutect2, varscan2
- NUP210L | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55146860; called by muse, mutect2, varscan2
- OR10P1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59007201; called by muse, mutect2, varscan2
- OR10Z1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 46/74 reads (62%) | catalogued as COSV63524679; called by muse, mutect2, varscan2
- OR1D5 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV73859510; called by muse, mutect2, varscan2
- OR1N2 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs868298889, COSV65460543; called by muse, mutect2
- OR5A2 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57392011; called by muse, mutect2, varscan2
- OR5AK2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58804413; called by muse, mutect2, varscan2
- OXCT2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV59593742; called by muse, mutect2, varscan2
- PALB2 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV55164746; called by muse, mutect2, varscan2
- PAPPA | c.4046C>T p.P1349L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60282342; called by muse, mutect2, varscan2
- PCDHB13 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV53396183; called by muse, mutect2, varscan2
- PCSK4 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs1052171084, COSV52013279; called by muse, mutect2, varscan2
- PDGFRB | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV53829759; called by muse, mutect2, varscan2
- PELP1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52587633; called by muse, mutect2, varscan2
- PGK2 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100505733, COSV59163640; called by muse, mutect2, varscan2
- PHF2 | c.1911T>A p.F637L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.952); catalogued as COSV63680614; called by muse, mutect2, varscan2
- PIK3CA | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV55920212; called by muse, mutect2, varscan2
- PIKFYVE | c.4285G>T p.E1429* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as rs779513989, COSV52240400; called by muse, mutect2, varscan2
- PLCZ1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs781129128, COSV56852141, COSV56852522; called by muse, mutect2, varscan2
- PLEKHG4B | c.1375G>A p.E459K (on ENST00000283426; = p.E815K on NM_052909.5) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV52047004; called by muse, mutect2, varscan2
- PLEKHN1 | c.704C>T p.P235L (on ENST00000379409; = p.P195L on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs553651354, COSV58021736; called by muse, mutect2
- PLG | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV51982566; called by muse, mutect2, varscan2
- PLG | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV51982573; called by muse, mutect2, varscan2
- POT1 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV62929672; called by muse, mutect2, varscan2
- PRAMEF17 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1232610838; called by muse, mutect2, varscan2
- PREX2 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV55767118; called by muse, mutect2, varscan2
- PRKCB | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57766582; called by muse, mutect2, varscan2
- PRRC2A | c.5376C>T p.A1792= | Splice Region (SNP) | VAF 26/85 reads (31%) | catalogued as COSV52990089; called by muse, mutect2, varscan2
- PRX | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs762202297, COSV99396600; called by muse, mutect2, varscan2
- PSME3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV53199024; called by muse, mutect2, varscan2
- PTCHD1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65059935; called by muse, mutect2, varscan2
- PTCHD1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV65059939; called by muse, mutect2, varscan2
- PTCHD3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71256336; called by muse, mutect2, varscan2
- PTGDR | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs1289539952, COSV60093719; called by muse, mutect2, varscan2
- PTGFRN | c.2564C>T p.S855F | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67798392; called by muse, mutect2, varscan2
- PTPN12 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV50357381; called by muse, mutect2, varscan2
- PTPRU | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60527149; called by muse, mutect2, varscan2
- PVALB | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53412276; called by muse, mutect2, varscan2
- RAD54L2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV56578339; called by muse, mutect2, varscan2
- RANBP2 | c.1102T>C p.F368L | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51700219; called by muse, mutect2, varscan2
- RANBP2 | c.7796C>T p.S2599F | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV51700228; called by muse, mutect2, varscan2
- RBL1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV60329729; called by muse, mutect2, varscan2
- RBM11 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV68748079; called by muse, mutect2, varscan2
- RBM6 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs764936183, COSV56482373; called by muse, mutect2, varscan2
- RETSAT | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV55525829; called by muse, mutect2, varscan2
- RHPN2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs764588726, COSV54278269; called by muse, mutect2
- RNF165 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV53971380; called by muse, mutect2, varscan2
- RNF17 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55039414; called by muse, mutect2, varscan2
- RYR2 | c.6343G>A p.D2115N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63682803; called by muse, mutect2, varscan2
- SAGE1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.395); catalogued as COSV100187254, COSV61013092; called by muse, mutect2, varscan2
- SBF2 | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV56298010; called by muse, mutect2, varscan2
- SDK1 | c.5774G>A p.G1925E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67366834; called by muse, mutect2
- SERTAD4 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs369366884; called by muse, mutect2, varscan2
- SF3B4 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV99641090; called by muse, mutect2, varscan2
- SF3B4 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99641092; called by muse, mutect2, varscan2
- SGCA | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV56249190; called by muse, mutect2, varscan2
- SGCZ | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV66013651; called by muse, varscan2
- SH3RF3 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV58685326; called by muse, mutect2, varscan2
- SI | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV52267005; called by muse, mutect2, varscan2
- SIN3B | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56132884; called by muse, mutect2, varscan2
- SLC14A2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54908616; called by muse, mutect2, varscan2
- SLC29A3 | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV64384992; called by muse, mutect2, varscan2
- SLC35D2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53562797; called by muse, mutect2, varscan2
- SLC38A1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV67063423; called by muse, mutect2, varscan2
- SLC8A3 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63520868; called by muse, mutect2, varscan2
- SORBS1 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53356933; called by muse, mutect2, varscan2
- SORL1 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52753846; called by muse, mutect2, varscan2
- SOX30 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53937257; called by muse, mutect2, varscan2
- SOX6 | c.1037T>G p.F346C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as COSV57044632; called by muse, mutect2, varscan2
- SPATA20 | c.2112C>T p.I704= (on ENST00000356488 / NM_001258372.1; = p.I720= on NM_022827.4) | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as rs1011286631, COSV50066493; called by muse, mutect2, varscan2
- SPG11 | c.6314C>T p.S2105F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55994313; called by muse, mutect2, varscan2
- SPG11 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55994322; called by muse, mutect2, varscan2
- SPHK1 | c.1144G>A p.E382K (on ENST00000392496 / NM_001355139.2; = p.E396K on NM_021972.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs1161256375, COSV60062692; called by muse, mutect2
- SPIN1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV65499233; called by muse, mutect2
- ST6GAL2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | PolyPhen probably damaging (0.967); catalogued as COSV64528016; called by muse, mutect2, varscan2
- STAR | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1408214109, CM156733, COSV52417364, COSV52418173; called by muse, mutect2, varscan2
- STRC | c.3308T>C p.V1103A | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV70834118; called by muse, mutect2, varscan2
- STRIP2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50804083; called by muse, mutect2, varscan2
- SVIL | c.3040G>A p.E1014K (on ENST00000355867 / NM_021738.3; = p.E588K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); catalogued as COSV63442938; called by muse, mutect2, varscan2
- SWI5 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100199626; called by mutect2, varscan2
- TANC1 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1406474412, COSV55087206; called by muse, mutect2, varscan2
- TFPT | c.245A>C p.Y82S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV58085154; called by muse, mutect2, varscan2
- TGM6 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs200872034, COSV52479670; called by muse, mutect2, varscan2
- THBS4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs747315970, COSV100644208, COSV63468749; called by muse, mutect2, varscan2
- TLL1 | c.1173T>A p.F391L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV50276200; called by muse, mutect2, varscan2
- TMEM132D | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV101242747; called by muse, mutect2, varscan2
- TMPRSS3 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1353827805, COSV52302471; called by muse, mutect2, varscan2
- TNFRSF8 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV55796158; called by muse, mutect2, varscan2
- TNRC6B | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV57294794; called by muse, mutect2, varscan2
- TP63 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV53204909, COSV53218443; called by muse, mutect2, varscan2
- TPTE | c.1118G>A p.R373Q (on ENST00000618007 / NM_199261.4; = p.R355Q on NM_199259.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568780841; called by muse, mutect2, varscan2
- TRIM65 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.393); catalogued as COSV53933017; called by muse, mutect2, varscan2
- TRPM4 | c.449-1G>A p.X150_splice | Splice Site (SNP) | VAF 39/110 reads (35%) | catalogued as rs1459312091, COSV53262369; called by muse, mutect2, varscan2
- TRPV3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV56791038; called by muse, mutect2, varscan2
- TRRAP | c.9584C>T p.S3195L (on ENST00000359863 / NM_001244580.1; = p.S3166L on NM_003496.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV62843588; called by muse, mutect2, varscan2
- TSPYL2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV60234633; called by mutect2, varscan2
- TTLL2 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs755211994, COSV53443728; called by muse, mutect2, varscan2
- TTN | c.58679G>A p.R19560Q (on ENST00000591111; = p.R12136Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | PolyPhen probably damaging (0.996); catalogued as rs763273464, COSV60023053; called by muse, mutect2, varscan2
- UGT1A9 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375970481; called by muse, mutect2, varscan2
- UGT2B10 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373059693, COSV55320047; called by muse, mutect2, varscan2
- UNC5C | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71659286; called by muse, mutect2, varscan2
- USP26 | c.584T>C p.L195S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV63708651; called by muse, mutect2, varscan2
- WDR90 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV53469280; called by muse, mutect2, varscan2
- XPO6 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58966063; called by muse, mutect2, varscan2
- ZDHHC5 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54706426; called by muse, mutect2, varscan2
- ZNF142 | c.4201C>T p.Q1401* (on ENST00000411696 / NM_001379660.1; = p.Q1201* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as rs778485502, COSV101376960, COSV68743592; called by muse, mutect2, varscan2
- ZNF16 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV52763495; called by muse, mutect2, varscan2
- ZNF207 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV58299755; called by muse, mutect2, varscan2
- ZNF334 | c.1280A>T p.H427L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV61618546; called by muse, mutect2, varscan2
- ZNF343 | c.895T>G p.C299G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53853603; called by muse, mutect2, varscan2
- ZNF345 | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV59323872; called by muse, mutect2, varscan2
- ZNF527 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV62230362; called by muse, mutect2, varscan2
- ZNHIT1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV59313085; called by muse, mutect2, varscan2
- ZNHIT1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as rs549828257, COSV100521990; called by muse, mutect2, varscan2
- AURKAIP1 | c.220dup p.L74Pfs*44 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CLSPN | c.1664_1675del p.V555_K558del | In Frame Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- DLG1 | c.2422C>T p.L808F (on ENST00000419354 / NM_001290983.1; = p.L830F on NM_004087.2) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2183G>A p.W728* | Nonsense Mutation (SNP) | VAF 117/310 reads (38%) | called by mutect2, varscan2
- POT1 | c.233_255+5del p.X78_splice | Splice Site (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- TPP2 | c.44_65del p.L15Qfs*55 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel*
- ABCD2 | c.1215G>A p.R405= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV58051498; called by muse, mutect2, varscan2
- ADAM12 | c.405C>A p.L135= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV64105871; called by muse, mutect2, varscan2
- ADAMTS18 | c.255G>A p.R85= | Silent (SNP) | VAF 120/288 reads (42%) | catalogued as COSV51398255; called by muse, mutect2, varscan2
- ADSS1 | c.366G>A p.K122= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV58273255; called by muse, mutect2, varscan2
- AFF2 | c.2364C>T p.I788= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV53987666; called by muse, mutect2, varscan2
- ANKRD11 | c.4938C>T p.D1646= | Silent (SNP) | VAF 84/163 reads (52%) | catalogued as COSV56360131; called by muse, mutect2, varscan2
- ANKS3 | c.516C>G p.P172= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58508820; called by muse, mutect2, varscan2
- ANO7 | c.1749C>T p.F583= (on ENST00000274979; = p.F529= on NM_001370694.2) | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs771272277, COSV51471214; called by muse, mutect2, varscan2
- APBA3 | c.522C>T p.P174= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV57462603; called by muse, mutect2, varscan2
- ARHGAP21 | c.2619C>T p.N873= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV57605387; called by muse, mutect2, varscan2
- ARID3B | c.1068C>T p.S356= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV60557468; called by muse, mutect2, varscan2
- ASPHD2 | c.225T>C p.C75= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV53218868; called by muse, mutect2, varscan2
- BDP1 | c.3969A>G p.L1323= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV62431071; called by muse, mutect2, varscan2
- C1S | c.1347C>T p.F449= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV61070831; called by muse, mutect2, varscan2
- C7 | c.1479G>A p.G493= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV57473810; called by muse, mutect2, varscan2
- CA5B | c.750A>G p.Q250= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs1267788394, COSV59416328; called by muse, mutect2, varscan2
- CABP4 | c.456G>A p.R152= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV56886198; called by muse, mutect2, varscan2
- CALHM5 | c.324G>A p.L108= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs781473154, COSV62067646; called by muse, mutect2, varscan2
- CASP14 | c.588G>A p.T196= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs778384693, COSV55665386; called by muse, mutect2, varscan2
- CCDC82 | c.1269C>T p.S423= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV53593232; called by muse, mutect2, varscan2
- CCK | c.177C>T p.G59= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV58183716; called by muse, mutect2, varscan2
- CD163L1 | c.183G>A p.V61= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs773248221, COSV58015331; called by muse, mutect2, varscan2
- CD207 | c.462C>T p.I154= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV69651754; called by muse, mutect2, varscan2
- CDH12 | c.1602C>T p.I534= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV66402204; called by muse, mutect2, varscan2
- CDH24 | c.474C>T p.T158= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs779938459, COSV52975802; called by muse, mutect2, varscan2
- CEMIP | c.1656G>T p.V552= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99586552; called by muse, mutect2, varscan2
- CGGBP1 | c.148C>T p.L50= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV58851787; called by muse, mutect2, varscan2
- CIB2 | c.114C>T p.A38= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV51948314; called by muse, mutect2, varscan2
- CLDN18 | c.69G>A p.A23= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs909983834, COSV99480756; called by muse, varscan2
- CLEC6A | c.201C>T p.F67= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV65987096; called by muse, mutect2, varscan2
- CNOT6 | c.87C>T p.S29= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV56161367, COSV99993435; called by muse, mutect2, varscan2
- CNR1 | c.339C>T p.P113= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV62987057; called by muse, mutect2, varscan2
- CNTNAP4 | c.2724C>T p.V908= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56677871; called by muse, mutect2, varscan2
- COL22A1 | c.696C>T p.R232= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV57334808; called by muse, mutect2, varscan2
- COPZ1 | c.402C>T p.I134= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs954224829, COSV50432300; called by muse, mutect2, varscan2
- D2HGDH | c.975C>T p.L325= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV58320050; called by muse, mutect2, varscan2
- DLG2 | c.1485G>A p.T495= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs776354298, COSV54640406; called by muse, mutect2, varscan2
- DNAH1 | c.7890C>T p.L2630= | Silent (SNP) | VAF 62/133 reads (47%) | catalogued as COSV70228531; called by muse, mutect2, varscan2
- DNAH9 | c.3690C>T p.F1230= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs576784942, COSV52347549; called by muse, mutect2, varscan2
- DNAH9 | c.7866C>T p.A2622= | Silent (SNP) | VAF 85/247 reads (34%) | catalogued as COSV52347568; called by muse, mutect2, varscan2
- DSCAM | c.441C>T p.I147= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1429420653, COSV68636959; called by muse, mutect2, varscan2
- DSG4 | c.2844G>A p.G948= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as rs1291284661, COSV57390340; called by muse, mutect2, varscan2
- DST | c.4698C>T p.V1566= | Silent (SNP) | VAF 87/247 reads (35%) | catalogued as COSV99754436; called by muse, mutect2, varscan2
- DUSP4 | c.1092C>T p.F364= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368211989; called by muse, mutect2
- DYTN | c.1476C>T p.P492= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV71751953; called by muse, mutect2, varscan2
- EEF1G | c.1311G>A p.K437= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1411911119, COSV61321526; called by muse, mutect2
- ELFN2 | c.2385G>A p.K795= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV68744454, COSV68746026; called by muse, mutect2, varscan2
- EPHA7 | c.2310C>T p.L770= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs375646884; called by muse, mutect2, varscan2
- ERBB4 | c.2571G>A p.V857= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs866930632, COSV61483808; called by muse, mutect2, varscan2
- EVPL | c.2433C>T p.S811= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1474733590, COSV56910398; called by muse, mutect2, varscan2
- FAM166C | c.510C>T p.P170= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs760769574, COSV56600449; called by muse, mutect2, varscan2
- FLRT3 | c.1218C>T p.P406= | Silent (SNP) | VAF 49/194 reads (25%) | catalogued as COSV99430125; called by muse, mutect2, varscan2
- FREM1 | c.375C>T p.V125= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs771731024, COSV66522730; called by muse, mutect2, varscan2
- FRS2 | c.1377C>T p.P459= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV54725278; called by muse, mutect2, varscan2
- GCN1 | c.4590G>A p.K1530= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56107282; called by muse, mutect2, varscan2
- GPX5 | c.537C>T p.I179= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV101297248, COSV69079347; called by muse, mutect2, varscan2
- GRIN3A | c.927C>T p.S309= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV62453149; called by muse, mutect2, varscan2
- GRTP1 | c.501A>C p.I167= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV58149869; called by muse, mutect2, varscan2
- GSPT1 | c.171C>T p.I57= (on ENST00000420576 / NM_001130007.2; = p.I195= on NM_002094.4) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV101341717; called by muse, mutect2, varscan2
- GUCY1A1 | c.2016G>A p.K672= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV56651351; called by muse, mutect2, varscan2
- H1-5 | c.297C>T p.T99= | Silent (SNP) | VAF 59/213 reads (28%) | catalogued as rs771428777, COSV58899895; called by muse, mutect2, varscan2
- HK3 | c.2427C>T p.I809= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1420605722, COSV52839574; called by muse, mutect2, varscan2
- IL1RAPL1 | c.198T>C p.L66= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV56258062; called by muse, mutect2, varscan2
- ITGAD | c.1806C>T p.A602= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs990106942, COSV66756876; called by muse, mutect2, varscan2
- KLHL13 | c.1812G>A p.E604= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV53247122; called by muse, mutect2, varscan2
- KPNA6 | c.825C>T p.A275= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as COSV65359976; called by muse, mutect2, varscan2
- L3MBTL3 | c.729G>A p.A243= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs570995365, COSV100695961; called by muse, mutect2, varscan2
- LAGE3 | c.294A>C p.T98= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV62074193; called by muse, mutect2, varscan2
- LPA | c.4155C>T p.V1385= | Silent (SNP) | VAF 57/164 reads (35%) | catalogued as COSV60300446; called by muse, mutect2, varscan2
- LRP4 | c.4617C>T p.I1539= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs151261586; called by muse, mutect2, varscan2
- LYZ | c.219G>A p.G73= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs748810774, COSV54260701; called by muse, mutect2, varscan2
- MAPK3 | c.654C>T p.N218= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV53773181; called by muse, mutect2, varscan2
- MBOAT1 | c.864C>A p.V288= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV61124756; called by muse, mutect2, varscan2
- MDH1B | c.339G>A p.G113= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100982170; called by muse, mutect2, varscan2
- MFSD2A | c.606G>A p.V202= (on ENST00000372809 / NM_001136493.3; = p.V189= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs781171252, COSV65685491; called by muse, mutect2, varscan2
- MMP12 | c.969C>T p.S323= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58259713; called by muse, mutect2, varscan2
- MTUS2 | c.597C>T p.S199= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV70916558; called by muse, mutect2, varscan2
- MUC4 | c.63C>T p.L21= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV62147241; called by muse, mutect2, varscan2
- MYH15 | c.5295G>A p.E1765= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV56309092; called by muse, mutect2, varscan2
- MYPN | c.195C>T p.A65= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100590254, COSV62733528; called by muse, mutect2, varscan2
- NFRKB | c.3372C>T p.V1124= (on ENST00000446488 / NM_001143835.2; = p.V1149= on NM_006165.3) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV58757762; called by muse, mutect2, varscan2
- NLRP14 | c.2142C>T p.F714= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV55066678; called by muse, mutect2, varscan2
- NTHL1 | c.159C>T p.S53= (on ENST00000219066; = p.S45= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99526255; called by muse, mutect2, varscan2
- NUDT7 | c.435C>T p.F145= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV51744600; called by muse, mutect2
- NYAP1 | c.711C>T p.P237= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV55718583; called by muse, varscan2
- OR10H2 | c.336C>T p.S112= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100008730; called by muse, mutect2, varscan2
- OR2M2 | c.1002C>T p.F334= | Silent (SNP) | VAF 61/109 reads (56%) | catalogued as COSV62898244; called by muse, mutect2, varscan2
- OR2T11 | c.144G>A p.V48= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV58185681; called by muse, mutect2, varscan2
- OR52B4 | c.129G>A p.G43= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1379349299, COSV68768858; called by muse, mutect2, varscan2
- OR52H1 | c.315C>T p.F105= (on ENST00000322653; = p.F111= on NM_001005289.1) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1179073253, COSV59505301; called by muse, mutect2, varscan2
- OR52K1 | c.876C>T p.I292= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV56903647; called by muse, mutect2, varscan2
- OR5A2 | c.924G>A p.R308= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs1207873141, COSV100119724; called by muse, mutect2, varscan2
- PCDHA3 | c.735G>A p.T245= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as rs782471663, COSV65364891; called by muse, mutect2, varscan2
- PDHA1 | c.1020G>T p.V340= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV58829251; called by muse, mutect2, varscan2
- PLEKHG1 | c.1242G>A p.L414= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV62047121; called by muse, mutect2, varscan2
- POTEH | c.495C>T p.F165= | Silent (SNP) | VAF 28/287 reads (10%) | catalogued as rs749778428, COSV58882371; called by muse, varscan2
- PRAMEF18 | c.696G>A p.R232= | Silent (SNP) | VAF 43/302 reads (14%) | called by muse, mutect2, varscan2
- PRX | c.3483G>A p.G1161= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs1344913169, COSV99396599; called by muse, mutect2, varscan2
- PSG11 | c.939C>A p.S313= | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as COSV60455001; called by muse, mutect2, varscan2
- PSG5 | c.111G>A p.T37= | Silent (SNP) | VAF 59/201 reads (29%) | catalogued as rs779213247, COSV61654114; called by muse, mutect2, varscan2
- PTAFR | c.57G>A p.P19= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs576953829, COSV59536532; called by muse, mutect2, varscan2
- QSOX2 | c.1953C>T p.F651= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs1564288168, COSV62394010; called by muse, mutect2, varscan2
- RASSF9 | c.819G>A p.L273= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV63433403; called by muse, mutect2, varscan2
- RHCG | c.1149G>A p.G383= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV51515737, COSV51518486; called by muse, mutect2, varscan2
- RNF213 | c.10419T>C p.P3473= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs754593604, COSV60396069; called by muse, mutect2, varscan2
- SCGB2A1 | c.180G>A p.G60= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV55276107; called by muse, mutect2, varscan2
- SCNN1B | c.852T>A p.L284= | Silent (SNP) | VAF 68/180 reads (38%) | catalogued as COSV56303930; called by muse, mutect2, varscan2
- SFSWAP | c.258C>T p.Y86= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs763805807, COSV55521696; called by muse, mutect2, varscan2
- SKA1 | c.279C>T p.S93= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53278783; called by muse, mutect2
- SLC13A1 | c.858G>A p.T286= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs151167581; called by muse, mutect2, varscan2
- SLC22A3 | c.708G>A p.S236= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs573086930, COSV51713112, COSV99279363; called by muse, mutect2, varscan2
- SLC28A1 | c.270C>T p.L90= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54478637, COSV99723284; called by muse, mutect2, varscan2
- SLC39A13 | c.270C>T p.P90= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1291377563, COSV100712662; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC39A13 | c.271C>T p.L91= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100712663; called by muse, mutect2, varscan2
- SLC6A17 | c.925T>C p.L309= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs1365674508, COSV58992873; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMAD6 | c.1323C>T p.F441= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1425838706, COSV56594546; called by muse, mutect2, varscan2
- SMAD6 | c.1440C>T p.F480= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56594556; called by muse, mutect2, varscan2
- SORBS3 | c.240C>T p.T80= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53552774; called by muse, mutect2, varscan2
- SPG7 | c.1959C>T p.S653= (on ENST00000268704; = p.S660= on NM_003119.4) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV51950241; called by muse, mutect2, varscan2
- SPRR3 | c.303C>T p.V101= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs267598047, COSV54879479; called by muse, varscan2
- SPTBN1 | c.6570C>T p.A2190= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV61688162; called by muse, mutect2, varscan2
- TACC2 | c.3555C>T p.H1185= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57754303; called by muse, mutect2, varscan2
- TENM4 | c.3258C>T p.F1086= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV53625491; called by muse, mutect2, varscan2
- THBS2 | c.1194C>T p.G398= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100827830; called by muse, mutect2, varscan2
- TIAM2 | c.627C>T p.S209= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV59693552; called by muse, mutect2, varscan2
- TMEM132A | c.2043C>T p.S681= (on ENST00000453848 / NM_178031.3; = p.S682= on NM_017870.4) | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV50004920; called by muse, mutect2, varscan2
- TMEM94 | c.3069C>T p.P1023= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs765049645, COSV58595227; called by muse, mutect2, varscan2
- TNK2 | c.975C>T p.T325= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV57368859; called by muse, mutect2, varscan2
- TPSAB1 | c.678G>A p.G226= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100126963; called by muse, varscan2
- TRHR | c.381C>T p.I127= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV61234002; called by muse, mutect2, varscan2
- TSPYL1 | c.945T>A p.P315= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV63994049; called by muse, mutect2, varscan2
- TTN | c.95310G>A p.V31770= (on ENST00000591111; = p.V24346= on NM_003319.4) | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV60023015; called by muse, mutect2, varscan2
- TUBGCP5 | c.2181C>T p.F727= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1320550584; called by muse, mutect2, varscan2
- UBE2NL | c.291C>T p.S97= | Silent (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- USHBP1 | c.807C>T p.L269= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV53103382; called by muse, mutect2, varscan2
- USP17L2 | c.1572G>A p.R524= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs749024656, COSV61555829; called by muse, varscan2
- USP29 | c.1071C>T p.V357= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV54142282, COSV99517939; called by muse, mutect2, varscan2
- WDR37 | c.357C>A p.S119= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54128528; called by muse, mutect2, varscan2
- ZNF345 | c.1158C>T p.I386= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV59323611, COSV59323876; called by muse, mutect2, varscan2
- ZNF497 | c.588C>T p.G196= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54050674; called by muse, mutect2, varscan2
- ZNF584 | c.844C>T p.L282= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1229794582, COSV59722212; called by muse, mutect2, varscan2
- ZNF676 | c.561C>T p.H187= (on ENST00000650058; = p.H155= on NM_001001411.3) | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs779786446, COSV68092962; called by muse, mutect2, varscan2
- ZYX | c.897C>T p.P299= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs766453615, COSV59556335; called by muse, mutect2, varscan2
- ZZEF1 | c.1725A>G p.G575= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as COSV101067720; called by muse, varscan2
- FAM169B | n.702G>A | RNA (SNP) | VAF 19/49 reads (39%) | catalogued as COSV60568626; called by muse, mutect2, varscan2
- FOXP1 | c.-298+39471T>A | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100599097; called by muse, mutect2, varscan2
- HMGB1P1 | n.70C>T | RNA (SNP) | VAF 58/188 reads (31%) | catalogued as rs758693908; called by muse, mutect2, varscan2
- KCNK1 | c.356-16562C>T | Intron (SNP) | VAF 30/43 reads (70%) | called by muse, mutect2, varscan2
- NXF5 | n.631C>T | RNA (SNP) | VAF 30/89 reads (34%) | catalogued as rs1455694174, COSV53790761; called by muse, mutect2, varscan2
- OSTCP1 | n.516C>T | RNA (SNP) | VAF 18/74 reads (24%) | catalogued as rs770975228; called by muse, mutect2, varscan2
- POLQ | chr3:121546474 G>T | 5'Flank (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- SMIM12 | chr1:34855429 A>G | 3'Flank (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101315061; called by muse, mutect2, varscan2
- TBCE | c.372-3526C>T | Intron (SNP) | VAF 40/61 reads (66%) | catalogued as COSV64005985; called by muse, mutect2, varscan2
